Gene-level copy-number profile of tumor specimen ALCH-AEOP-TTP1-A from ALCHEMIST case ALCH-AEOP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 59.8 years (21,836 days).
Specimen ALCH-AEOP-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 909be0c9-21b7-4cb0-b794-3143689f12de.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEOP-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,751 have no estimate.
https://portal.gdc.cancer.gov/files/87908beb-c4d0-4133-a071-4e4f29663c24

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 70; copy number 1: 3,585; copy number 2: 51,294; copy number 3: 3,436; copy number 4: 384; copy number 5: 14; copy number 6: 26; copy number 8: 2; copy number 9: 41; copy number 11: 4; copy number 16: 16.

Homozygous deletions (total copy number 0; autosomes only): 40 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:1,009,936–1,026,898, 1 gene: FGFRL1.
- chr7:983,181–989,640, 1 gene: CYP2W1.
- chr7:1,508,655–1,509,427, 1 gene: AC093734.1.
- chr7:128,739,292–128,773,400, 2 genes (within-gene range 0–2): CALU, RN7SL81P.
- chr9:136,483,495–136,486,067, 1 gene (within-gene range 0–1): C9orf163.
- chr16:1,782,932–1,794,971, 2 genes (within-gene range 0–2): NUBP2, IGFALS.
- chr19:637,105–683,392, 5 genes: AC004449.1, FGF22, RNF126, AC004156.1, FSTL3.
- chr19:47,290,023–47,322,066, 1 gene: C5AR1.
- chr21:7,744,962–8,454,792, 26 genes: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 103 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:32,635,673–32,788,944, 14 genes, copy number 5: AC133569.1, AC138907.7, AC138907.5, AC138907.1, TP53TG3, AC138907.3, AC138907.6, ABHD17AP7, AC138907.2, AC138907.4, HERC2P5, AC138907.8, AC138907.9, AC138907.10.
- chr17:15,436,015–16,804,453, 67 genes, copy number 6–9 (within-gene range 2–9) (broad region; genes not listed).
- chr17:39,566,915–39,877,896, 16 genes, copy number 16: AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2.
- chr22:18,400,407–18,512,187, 4 genes, copy number 11: PPP1R26P3, FAM230A, AC023490.2, FAM247B.
- chr22:18,636,445–18,653,617, 2 genes, copy number 8: CA15P2, PPP1R26P2.

Autosomal genes at a single copy (total copy number 1): 807. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
